Somatic mutation profile of tumor specimen TCGA-78-7220-01A (aliquot TCGA-78-7220-01A-11D-2036-08) from TCGA case TCGA-78-7220, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.3 years (19,480 days).
Specimen TCGA-78-7220-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 526a5161-6921-4c86-9c96-629573f09efd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7220-10A (Blood Derived Normal), aliquot TCGA-78-7220-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccb0546a-7557-44e6-8fbd-39df6c72e998

The open-access MAF lists 914 somatic variants for this specimen: 685 protein-altering or splice-affecting, 208 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 579, Silent 208, Nonsense Mutation 54, Splice Site 24, Frame Shift Del 20, RNA 7, Intron 4, Splice Region 3, Frame Shift Ins 3, 3'Flank 3, 5'UTR 3, 5'Flank 3.

Variants (750 of 914; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as rs137854617, CM024645, COSV61118622; ClinVar: not provided / pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TCTN1 | c.978+1G>T p.X326_splice (on ENST00000551590 / NM_001173975.3; = p.X312_splice on NM_024549.6) | Splice Site (SNP) | VAF 29/56 reads (52%) | catalogued as rs886039436, COSV66542501; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 66/92 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as COSV67018971; called by muse, mutect2, varscan2
- ABCC8 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV56852133, COSV56857129; called by muse, varscan2
- ABI2 | c.1348C>T p.R450C (on ENST00000295851 / NM_001375719.1; = p.R412C on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs779436109, COSV53695982; called by muse, mutect2, varscan2
- ABL1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59335679, COSV59340314; called by muse, mutect2, varscan2
- ABR | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1353956639, COSV56843108; called by muse, mutect2, varscan2
- AC006059.2 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV59606914; called by muse, mutect2, varscan2
- AC100868.1 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV51849411; called by muse, mutect2
- AC132217.2 | c.61A>T p.T21S | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.058); catalogued as COSV56101567; called by muse, mutect2, varscan2
- ACAN | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV61368682; called by muse, mutect2, varscan2
- ACOX2 | c.1892A>G p.D631G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57150734; called by muse, mutect2, varscan2
- ACP3 | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 69/115 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as COSV60488482; called by muse, mutect2, varscan2
- ACSL6 | c.1171del p.E391Sfs*40 (on ENST00000379240; = p.E416Sfs*40 on NM_015256.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/73 reads (55%) | catalogued as COSV99733369; called by mutect2, pindel, varscan2
- ACTR1A | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64024152; called by muse, mutect2, varscan2
- ACVR2A | c.629A>T p.Q210L | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV54028675; called by muse, mutect2, varscan2
- ADAM22 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55989415, COSV99068231; called by muse, mutect2, varscan2
- ADAMTS12 | c.787G>T p.G263W | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412169809, COSV61278172; called by muse, varscan2
- ADAMTS16 | c.3160C>A p.Q1054K | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57006024; called by muse, mutect2, varscan2
- ADAMTS17 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV51492888; called by muse, mutect2, varscan2
- ADAMTS3 | c.2209G>T p.G737W | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54401868; called by muse, mutect2, varscan2
- ADAMTS7 | c.3769G>T p.V1257L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV66309310; called by muse, mutect2, varscan2
- ADCY2 | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs759548641, COSV100602445, COSV57897991; called by muse, mutect2
- ADGRG4 | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV54962103; called by muse, mutect2, varscan2
- AGXT | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV56755669; called by muse, mutect2, varscan2
- AGXT2 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs183850114; called by muse, mutect2, varscan2
- ALK | c.3752C>A p.A1251D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66588254; called by muse, mutect2, varscan2
- ANKRD17 | c.5456G>C p.G1819A | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.104); catalogued as COSV58227294; called by muse, mutect2, varscan2
- ANKRD50 | c.2785G>T p.V929F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV72386258; called by muse, mutect2, varscan2
- APBB2 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs980055022, COSV55961676; called by muse, mutect2, varscan2
- APC | c.3476C>T p.P1159L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.272); catalogued as CD067143, COSV57379644, COSV99073010; called by muse, mutect2, varscan2
- APC2 | c.5618C>T p.S1873F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763831600, COSV52021885; called by muse, mutect2, varscan2
- APOB | c.7837C>A p.Q2613K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as COSV51951071; called by muse, mutect2, varscan2
- APOL2 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); catalogued as rs776152288, COSV50773047; called by muse, mutect2, varscan2
- APP | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as COSV61004462; called by muse, mutect2, varscan2
- ARHGAP11A | c.2763G>T p.M921I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs770000624, COSV55708418; called by muse, mutect2, varscan2
- ARHGAP15 | c.764T>G p.L255* | Nonsense Mutation (SNP) | VAF 72/126 reads (57%) | catalogued as COSV54519471; called by muse, mutect2, varscan2
- ARHGEF25 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424455112, COSV54090321; called by muse, mutect2, varscan2
- ARIH1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV65910786; called by muse, mutect2, varscan2
- ARMC12 | c.925G>T p.A309S (on ENST00000373866 / NM_001286574.2; = p.A336S on NM_145028.5) | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV55361602; called by muse, mutect2, varscan2
- ARSB | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV53728786; called by muse, mutect2, varscan2
- ARSF | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV63841003; called by muse, mutect2, varscan2
- ARSG | c.1267G>C p.V423L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as COSV71593962; called by muse, mutect2
- ARSH | c.924C>A p.D308E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV66963825; called by muse, mutect2, varscan2
- ASF1B | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV54616991, COSV99654431; called by muse, mutect2, varscan2
- ASIC4 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61733344; called by muse, mutect2, varscan2
- ASPH | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV65247334; called by muse, mutect2, varscan2
- ASPM | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54127403, COSV54138082; called by muse, mutect2, varscan2
- ASTL | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | catalogued as COSV60905330; called by muse, mutect2, varscan2
- ASTN1 | c.3370C>A p.L1124M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1308661837, COSV62505580; called by muse, mutect2, varscan2
- ASTN1 | c.2518A>T p.T840S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV56083577, COSV56088115; called by muse, mutect2, varscan2
- ASTN1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 47/93 reads (51%) | catalogued as COSV56082310, COSV56083591; called by muse, mutect2, varscan2
- ATG7 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 27/133 reads (20%) | catalogued as COSV61615496; called by muse, mutect2, varscan2
- ATP2A1 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100706809, COSV62870850, COSV62871192; called by muse, mutect2, varscan2
- ATP2B3 | c.1824-1G>A p.X608_splice | Splice Site (SNP) | VAF 39/59 reads (66%) | catalogued as COSV54851432; called by muse, mutect2, varscan2
- ATP6V1F | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs200558362, COSV50800269; called by muse, mutect2, varscan2
- ATRNL1 | c.3830G>T p.R1277L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs370291248, COSV58096061; called by muse, mutect2, varscan2
- ATRX | c.4504G>T p.E1502* | Nonsense Mutation (SNP) | VAF 64/141 reads (45%) | catalogued as COSV64882548, COSV64882905; called by muse, mutect2, varscan2
- BARHL2 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64981991; called by muse, mutect2, varscan2
- BCOR | c.4577G>T p.S1526I (on ENST00000378444 / NM_001123385.2; = p.S1492I on NM_017745.6) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60717639; called by muse, mutect2, varscan2
- BICDL2 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.043); catalogued as rs1254112617, COSV54157896; called by muse, mutect2, varscan2
- BMP3 | c.1190A>T p.Y397F | Missense Mutation (SNP) | VAF 143/226 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV51094553; called by muse, mutect2, varscan2
- BPIFC | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV55915625; called by muse, mutect2, varscan2
- BTBD9 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV58422636; called by muse, mutect2, varscan2
- C12orf40 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV61137418; called by muse, mutect2, varscan2
- C12orf40 | c.1090A>G p.K364E | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV61137433; called by muse, mutect2, varscan2
- C12orf66 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV61323750, COSV61324643; called by muse, mutect2, varscan2
- C1orf198 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs773439874, COSV64176424; called by muse, mutect2, varscan2
- C2CD3 | c.5753C>T p.A1918V | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV58100450; called by muse, mutect2, varscan2
- CACNA1B | c.4910A>G p.N1637S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53147220; called by muse, mutect2, varscan2
- CACNA1E | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV62417857; called by muse, mutect2, varscan2
- CACNA1E | c.6208G>T p.G2070C (on ENST00000367573 / NM_001205293.3; = p.G2027C on NM_000721.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62417918; called by muse, mutect2, varscan2
- CACNA1F | c.4513T>G p.C1505G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59906839; called by muse, mutect2
- CACNA1F | c.4511C>A p.A1504D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59906843; called by muse, mutect2
- CAD | c.2563G>T p.G855* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as COSV53031497; called by muse, mutect2, varscan2
- CALCRL | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV66474682; called by muse, mutect2, varscan2
- CALHM5 | c.64T>G p.F22V | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV62068611; called by muse, mutect2
- CAMKV | c.748C>G p.P250A | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56557661; called by muse, mutect2, varscan2
- CAPN6 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs139917382, COSV60697088; called by muse, mutect2, varscan2
- CAPRIN1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58222256; called by muse, mutect2, varscan2
- CARS2 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV57288966; called by muse, mutect2, varscan2
- CARS2 | c.393+1G>T p.X131_splice | Splice Site (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99959975; called by muse, mutect2, varscan2
- CBLN2 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV54052936; called by muse, mutect2, varscan2
- CCDC144A | c.2455C>T p.H819Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as COSV60701638; called by muse, mutect2, varscan2
- CCL8 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV67014202; called by muse, mutect2, varscan2
- CCT8L2 | c.1588C>A p.Q530K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs1432510693, COSV63463712; called by muse, mutect2, varscan2
- CD163 | c.2098C>A p.P700T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63136864; called by muse, mutect2, varscan2
- CD163 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 73/219 reads (33%) | catalogued as COSV100776108; called by muse, mutect2, varscan2
- CD163 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.73); catalogued as rs746457366, COSV100776109; called by muse, mutect2, varscan2
- CD1E | c.977A>T p.D326V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as COSV63772776; called by muse, mutect2, varscan2
- CD22 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV50066892; called by muse, mutect2, varscan2
- CD244 | c.975G>A p.K325= (on ENST00000368033 / NM_001166663.2; = p.K320= on NM_016382.4) | Splice Region (SNP) | VAF 30/58 reads (52%) | catalogued as COSV100458216, COSV59241375; called by muse, mutect2, varscan2
- CDC42BPG | c.3145G>T p.E1049* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV61349096; called by muse, mutect2, varscan2
- CDH10 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52584948; called by muse, mutect2, varscan2
- CDH10 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570779, COSV52574921; called by muse, mutect2, varscan2
- CDH12 | c.1978T>A p.Y660N | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66444829; called by muse, mutect2, varscan2
- CDH22 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs774541182, COSV64839582; called by muse, mutect2, varscan2
- CDH23 | c.7302T>A p.F2434L | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV56487628; called by muse, mutect2, varscan2
- CDH4 | c.2619C>G p.S873R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV64642070, COSV64673335; called by muse, mutect2, varscan2
- CDKAL1 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV51191261; called by muse, mutect2, varscan2
- CEP128 | c.2804G>T p.R935I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV55389566; called by muse, mutect2, varscan2
- CEP164 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV54045953; called by muse, mutect2, varscan2
- CEP170B | c.4444G>A p.E1482K (on ENST00000453495; = p.E1411K on NM_015005.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs1330976569, COSV52044681; called by muse, mutect2, varscan2
- CFAP61 | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV55646197; called by muse, mutect2, varscan2
- CHD2 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV67714149; called by muse, mutect2, varscan2
- CHMP7 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV57533479, COSV57533840; called by muse, mutect2, varscan2
- CMAS | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as COSV57557499; called by muse, mutect2, varscan2
- CMTM5 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV59307641; called by muse, mutect2, varscan2
- CNGB3 | c.701G>T p.C234F | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs766852205, COSV60697828; called by muse, mutect2, varscan2
- CNNM2 | c.695C>G p.T232S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV63996425; called by muse, mutect2, varscan2
- CNR1 | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV62991054; called by muse, mutect2, varscan2
- CNTN2 | c.2962G>A p.G988R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV59352729; called by muse, mutect2, varscan2
- CNTNAP4 | c.594A>T p.Q198H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV56699009; called by muse, mutect2, varscan2
- COL10A1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV54574547; called by muse, mutect2, varscan2
- COL11A1 | c.424C>G p.H142D | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV62196182; called by muse, mutect2, varscan2
- COL12A1 | c.7439T>C p.V2480A | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV59407155; called by muse, mutect2, varscan2
- COL16A1 | c.3551A>G p.E1184G | Missense Mutation (SNP) | VAF 74/114 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV54713257; called by muse, mutect2, varscan2
- COL19A1 | c.1954C>A p.P652T | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59577924, COSV59587123; called by muse, mutect2, varscan2
- COL1A2 | c.2275G>T p.V759F | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV51965605; called by muse, mutect2, varscan2
- COL25A1 | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as rs1437816010, COSV67657914; called by muse, mutect2, varscan2
- COL28A1 | c.1860+1G>T p.X620_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV68084426; called by muse, mutect2, varscan2
- COQ7 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV58982570; called by muse, mutect2, varscan2
- CPM | c.420C>A p.Y140* | Nonsense Mutation (SNP) | VAF 13/215 reads (6%) | catalogued as COSV58035776; called by muse, mutect2
- CPXM1 | c.2106G>C p.K702N | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV66046709; called by muse, mutect2, varscan2
- CREBBP | c.6130G>T p.A2044S | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.077); catalogued as COSV52139714; called by muse, varscan2
- CRYBB3 | c.194+1G>T p.X65_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as rs200444299, COSV53195467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.5599G>T p.A1867S (on ENST00000520002; = p.A1866S on NM_033225.6) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV59379127; called by muse, mutect2, varscan2
- CSMD1 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV68254967; called by muse, mutect2
- CSMD3 | c.5771C>A p.S1924Y (on ENST00000297405 / NM_001363185.1; = p.S1820Y on NM_052900.3) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs968189357, COSV52153924; called by muse, varscan2
- CSMD3 | c.1670G>C p.G557A (on ENST00000297405 / NM_001363185.1; = p.G453A on NM_052900.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52307871; called by muse, mutect2, varscan2
- CT83 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.319); catalogued as COSV64141451; called by muse, mutect2, varscan2
- CUBN | c.6233G>A p.S2078N | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64726492; called by muse, mutect2, varscan2
- CUEDC2 | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as COSV50059863; called by muse, mutect2, varscan2
- CUX2 | c.4073G>T p.C1358F | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV55646869; called by muse, mutect2, varscan2
- CYP11A1 | c.1449C>A p.F483L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51432975, COSV51434699; called by muse, mutect2, varscan2
- CYP11B1 | c.1121+1G>A p.X374_splice | Splice Site (SNP) | VAF 48/105 reads (46%) | catalogued as COSV52830162; called by muse, mutect2, varscan2
- CYP11B2 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); catalogued as COSV59997703; called by muse, mutect2, varscan2
- CYP2C19 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV64909223; called by muse, mutect2, varscan2
- DAB1 | c.438+2T>A p.X146_splice | Splice Site (SNP) | VAF 33/61 reads (54%) | catalogued as COSV59736487; called by muse, mutect2, varscan2
- DACH2 | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV64184677; called by muse, mutect2, varscan2
- DALRD3 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781227318, COSV58246130, COSV58247362; called by muse, mutect2, varscan2
- DCAF11 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.194); catalogued as COSV58110654; called by muse, mutect2, varscan2
- DCC | c.3638C>A p.A1213E | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV71440168; called by muse, mutect2, varscan2
- DCC | c.3817C>A p.P1273T | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as COSV71435874; called by muse, mutect2, varscan2
- DCDC1 | c.3458C>A p.S1153* (on ENST00000597505 / NM_001367979.1; = p.S260* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV60312386; called by muse, mutect2, varscan2
- DCDC1 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV60857447; called by muse, mutect2, varscan2
- DCLK3 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 34/62 reads (55%) | catalogued as COSV101374115, COSV69364041; called by muse, mutect2, varscan2
- DHCR7 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as COSV100831779, COSV62795146, COSV62796610; called by muse, mutect2, varscan2
- DHX57 | c.2164+2T>A p.X722_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54890796; called by muse, mutect2, varscan2
- DIDO1 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs778691703, COSV56633387; called by muse, mutect2, varscan2
- DMD | c.3128T>C p.L1043P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63789105; called by muse, mutect2, varscan2
- DMRT1 | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV101206654, COSV66524524; called by muse, mutect2, varscan2
- DNAH3 | c.2500C>G p.R834G | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54549148; called by muse, mutect2, varscan2
- DNAH5 | c.7387C>T p.Q2463* | Nonsense Mutation (SNP) | VAF 11/133 reads (8%) | catalogued as rs747090720, BM1230713, COSV54250008; called by muse, mutect2
- DNAH8 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59478308; called by muse, mutect2, varscan2
- DNAJB8 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV59879504; called by muse, mutect2, varscan2
- DOCK2 | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV56972851; called by muse, mutect2, varscan2
- DOCK3 | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56547976, COSV99813725; called by muse, mutect2, varscan2
- DPP9 | c.525G>T p.M175I (on ENST00000598800; = p.M204I on NM_139159.5) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV53594185; called by muse, mutect2, varscan2
- DPYSL3 | c.949A>T p.I317F | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV58330796; called by muse, mutect2, varscan2
- DPYSL5 | c.715-1G>T p.X239_splice | Splice Site (SNP) | VAF 19/75 reads (25%) | catalogued as COSV56515943; called by muse, mutect2, varscan2
- DRD1 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.389); catalogued as COSV67105189; called by muse, mutect2, varscan2
- DSG2 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV55202678; called by muse, mutect2, varscan2
- DST | c.517T>A p.C173S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56845210; called by muse, mutect2
- DTX2 | c.66G>C p.W22C | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56864850; called by muse, mutect2, varscan2
- DUSP3 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56824306, COSV56825295, COSV56825505; called by muse, mutect2, varscan2
- DUSP9 | c.1137C>A p.F379L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV61438433; called by muse, mutect2
- DYNC2I1 | c.2844G>T p.W948C | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68107040; called by muse, mutect2, varscan2
- DYNLL1 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 62/179 reads (35%) | catalogued as COSV54359548, COSV54360041; called by muse, mutect2, varscan2
- EGFL6 | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV63635185; called by muse, mutect2, varscan2
- EGFLAM | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 51/421 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59316079; called by muse, mutect2, varscan2
- EMILIN3 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs933841080, COSV60038622; called by muse, mutect2, varscan2
- EPHA3 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 132/225 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1194420863, COSV100348419; called by muse, mutect2, varscan2
- EPHA3 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60704315; called by muse, mutect2, varscan2
- ERC1 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV61697625; called by muse, mutect2, varscan2
- ERICH3 | c.2471A>C p.E824A | Missense Mutation (SNP) | VAF 75/109 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV58617450; called by muse, mutect2, varscan2
- ERICH3 | c.2268C>A p.N756K | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV58610677, COSV58617464; called by muse, mutect2, varscan2
- ESCO2 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59416389; called by muse, mutect2, varscan2
- F13A1 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1482093853, COSV53566829; called by muse, mutect2, varscan2
- F8 | c.6230C>A p.S2077* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as CM010880, COSV64278329; called by muse, mutect2, varscan2
- FADS2 | c.972C>A p.N324K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV53896565, COSV53902112; called by muse, mutect2, varscan2
- FAM120C | c.2905G>C p.A969P | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60262335; called by muse, mutect2, varscan2
- FAM120C | c.1938G>T p.E646D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.105); catalogued as COSV60262345; called by muse, mutect2, varscan2
- FAM124A | c.1369C>T p.H457Y (on ENST00000322475 / NM_001242312.2; = p.H493Y on NM_145019.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771738151, COSV54479953; called by muse, mutect2, varscan2
- FAM135B | c.3984G>T p.M1328I | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52751663; called by muse, mutect2, varscan2
- FAM47B | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs202142258, COSV61456638; called by muse, mutect2, varscan2
- FAM83A | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV52687884; called by muse, mutect2, varscan2
- FAM83B | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV60926472; called by muse, mutect2, varscan2
- FAM83B | c.2639G>C p.R880T | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100173974, COSV60922627, COSV60926479; called by muse, mutect2, varscan2
- FANCM | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV57500647, COSV57506171; called by mutect2, varscan2
- FAR2 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV51729524; called by muse, mutect2, varscan2
- FAT3 | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53169888; called by muse, mutect2, varscan2
- FAT4 | c.10895G>T p.G3632V | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV58707074; called by muse, mutect2, varscan2
- FAT4 | c.12431G>C p.R4144T | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58673092, COSV58707096; called by muse, mutect2, varscan2
- FBXL7 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV61652765; called by muse, mutect2, varscan2
- FBXL7 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61652769; called by muse, mutect2, varscan2
- FBXO47 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV65242774; called by muse, mutect2, varscan2
- FFAR4 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.111); catalogued as COSV65179717; called by muse, mutect2, varscan2
- FGF6 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV57405151; called by muse, mutect2, varscan2
- FGFRL1 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53259328; called by muse, mutect2, varscan2
- FJX1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58554004; called by muse, mutect2, varscan2
- FLG | c.11696C>G p.S3899C | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1285546104, COSV64248396; called by muse, mutect2, varscan2
- FLT4 | c.1173G>T p.E391D | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56121319; called by muse, mutect2, varscan2
- FMN2 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs754768476, COSV60433685, COSV60451990; called by muse, mutect2, varscan2
- FRG1 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs775245735, COSV57004006, COSV57007609; called by muse, varscan2
- FRMD6 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1378137502, COSV61090646; called by muse, mutect2, varscan2
- FRMPD4 | c.1664C>G p.P555R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1399115930, COSV66222715; called by muse, mutect2, varscan2
- FRMPD4 | c.2908G>T p.A970S | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV66212620, COSV66222724; called by muse, mutect2, varscan2
- FRYL | c.1798C>G p.L600V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51961296; called by muse, mutect2, varscan2
- FSCB | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV61219450; called by muse, mutect2, varscan2
- FSHB | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54222785; called by muse, mutect2, varscan2
- FSTL5 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60227175; called by muse, mutect2, varscan2
- FUT3 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV99744937; called by muse, mutect2, varscan2
- GABRA5 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV59482309; called by muse, mutect2, varscan2
- GABRB1 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV54998472; called by muse, mutect2, varscan2
- GABRG2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 32/45 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV62722295; called by muse, mutect2, varscan2
- GDF3 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV61713623; called by muse, mutect2, varscan2
- GDF7 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55348630; called by muse, mutect2, varscan2
- GIT1 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV56612332; called by muse, mutect2, varscan2
- GLI3 | c.3581G>C p.C1194S | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV67894542; called by muse, mutect2, varscan2
- GLRA2 | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54346373, COSV54347285; called by muse, mutect2, varscan2
- GLYATL2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs377489659; called by muse, mutect2, varscan2
- GNGT1 | c.92T>A p.M31K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV50353473; called by muse, mutect2, varscan2
- GOLGA6B | c.625G>C p.A209P | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV69770593; called by muse, mutect2, varscan2
- GPC6 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV65536132; called by muse, mutect2, varscan2
- GPR148 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV59309373; called by muse, mutect2, varscan2
- GPRASP2 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59992424; called by muse, mutect2, varscan2
- GPSM3 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs771329481, COSV66683613; called by muse, mutect2, varscan2
- GRAMD4 | c.1518G>T p.K506N | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV63032462; called by muse, mutect2, varscan2
- GRIA4 | c.487+1del | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as COSV56882353; called by mutect2, pindel, varscan2
- GRIK2 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 133/320 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV59769271; called by muse, mutect2, varscan2
- GRIK2 | c.1992G>A p.M664I | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59738547; called by muse, mutect2, varscan2
- GRIN2A | c.3424C>A p.P1142T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.315); catalogued as COSV58055710; called by muse, mutect2, varscan2
- GRIN2B | c.2698C>G p.R900G | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV74204785, COSV74207615; called by muse, mutect2, varscan2
- GRIN3A | c.1960G>T p.G654C | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62457899; called by muse, mutect2, varscan2
- GRM5 | c.1000G>T p.V334F | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100551729, COSV59627532; called by muse, mutect2, varscan2
- GSDMB | c.989G>C p.R330P (on ENST00000418519 / NM_001165958.1; = p.R308P on NM_018530.2) | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs373291897, COSV58782521, COSV58782755; called by muse, mutect2, varscan2
- GTF3C1 | c.2284G>T p.G762* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV62244677; called by muse, mutect2, varscan2
- GTF3C2 | c.1625A>T p.Q542L | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV53128662, COSV53129298; called by muse, mutect2, varscan2
- GUCA1B | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 145/212 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV50004489, COSV50005311; called by muse, mutect2, varscan2
- H3C2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV52518070, COSV52519869; called by muse, mutect2, varscan2
- HEPHL1 | c.3439C>G p.Q1147E | Missense Mutation (SNP) | VAF 100/197 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs768755506, COSV59896128; called by muse, mutect2, varscan2
- HESX1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV55843691; called by muse, mutect2, varscan2
- HIPK4 | c.1094C>A p.S365* | Nonsense Mutation (SNP) | VAF 130/169 reads (77%) | catalogued as COSV52520602, COSV99397042; called by muse, mutect2, varscan2
- HIPK4 | c.1093T>A p.S365T | Missense Mutation (SNP) | VAF 128/167 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV99397047; called by muse, mutect2, varscan2
- HRNR | c.418T>G p.Y140D | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV64262412; called by muse, mutect2, varscan2
- HSPA4L | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV56548399; called by muse, mutect2, varscan2
- HYAL4 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as COSV56140319; called by muse, mutect2, varscan2
- HYDIN | c.446A>C p.D149A | Missense Mutation (SNP) | VAF 72/102 reads (71%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as COSV55498328; called by muse, mutect2, varscan2
- IBSP | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV56897236; called by muse, mutect2, varscan2
- ICE1 | c.811A>C p.M271L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV56831815; called by muse, mutect2, varscan2
- ICE1 | c.5286G>T p.R1762S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56831830; called by muse, mutect2, varscan2
- IGSF1 | c.2689G>T p.G897W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812341, COSV63840149; called by muse, mutect2, varscan2
- IGSF10 | c.3721G>C p.A1241P | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV56791272; called by muse, mutect2, varscan2
- INPP5D | c.2529G>T p.L843F (on ENST00000445964 / NM_001017915.3; = p.L842F on NM_005541.5) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV64040121; called by muse, mutect2, varscan2
- IQGAP3 | c.4439G>T p.R1480L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63252306, COSV63254445; called by muse, mutect2, varscan2
- IQSEC3 | c.545G>T p.R182M | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV58290537; called by muse, mutect2, varscan2
- IRX1 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV57360141, COSV57362250; called by muse, varscan2
- IRX2 | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1418966314, COSV57413536; called by muse, mutect2, varscan2
- ITGA7 | c.711C>A p.D237E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.119); catalogued as COSV57700725; called by muse, mutect2, varscan2
- ITGAX | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as rs200451726, COSV51651174; called by muse, mutect2, varscan2
- ITIH5 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.503); catalogued as rs1459942059, COSV56914063; called by muse, mutect2, varscan2
- ITLN1 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV58276693; called by muse, mutect2, varscan2
- ITSN1 | c.527-2A>C p.X176_splice | Splice Site (SNP) | VAF 15/38 reads (39%) | catalogued as COSV66085879; called by muse, mutect2, varscan2
- ITSN2 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV61953713; called by muse, mutect2, varscan2
- KATNIP | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.037); catalogued as COSV55179452; called by muse, mutect2, varscan2
- KCNH8 | c.323G>T p.W108L | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV60475700; called by muse, mutect2, varscan2
- KCNJ16 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52257076; called by muse, mutect2, varscan2
- KCNU1 | c.3190C>A p.Q1064K | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV67759627; called by muse, mutect2, varscan2
- KCNV2 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV66057475; called by muse, mutect2, varscan2
- KCTD19 | c.473T>G p.L158R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58574968; called by muse, mutect2, varscan2
- KDM6B | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV54686557; called by muse, mutect2, varscan2
- KIAA1586 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV66056681, COSV66057402; called by muse, mutect2, varscan2
- KIF1A | c.2264C>A p.T755K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV57500844; called by muse, mutect2, varscan2
- KIF23 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV52981381, COSV52982763; called by muse, mutect2
- KIRREL2 | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52879898; called by muse, mutect2, varscan2
- KRCC1 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.05); catalogued as COSV61252191; called by muse, mutect2, varscan2
- KRT33B | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV52441438, COSV52442296; called by muse, mutect2, varscan2
- KRT82 | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144000317, COSV57787169; called by muse, mutect2, varscan2
- KRTAP5-8 | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 106/606 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.767); catalogued as COSV68324928; called by muse, varscan2
- KRTAP5-8 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 99/478 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1237220412, COSV68324933; called by muse, varscan2
- L1CAM | c.3237C>A p.D1079E | Missense Mutation (SNP) | VAF 133/204 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV62830046; called by muse, mutect2, varscan2
- L2HGDH | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV55560501; called by muse, mutect2, varscan2
- LAMA2 | c.1487A>T p.D496V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV70354591; called by muse, mutect2, varscan2
- LAMA4 | c.4901C>T p.T1634I (on ENST00000230538 / NM_001105206.3; = p.T1627I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1194804981, COSV57904376; called by muse, mutect2, varscan2
- LAMA5 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV53371647; called by muse, mutect2, varscan2
- LARGE1 | c.1898G>A p.G633D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61671569; called by muse, mutect2, varscan2
- LARP1 | c.1639G>C p.A547P (on ENST00000518297 / NM_033551.3; = p.A470P on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV60431026; called by muse, mutect2, varscan2
- LARS1 | c.3144C>G p.I1048M (on ENST00000394434 / NM_020117.11; = p.I1021M on NM_016460.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1342723974, COSV50987904; called by muse, mutect2, varscan2
- LCA5L | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV55747246; called by muse, mutect2, varscan2
- LCMT1 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV66727114; called by muse, mutect2, varscan2
- LECT2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50847623; called by muse, mutect2, varscan2
- LGALS9C | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60196301, COSV60196623; called by muse, mutect2, varscan2
- LGR4 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV64866161; called by muse, mutect2, varscan2
- LGR5 | c.2325C>A p.N775K | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57009644; called by muse, mutect2, varscan2
- LHX8 | c.994+2T>C p.X332_splice | Splice Site (SNP) | VAF 46/75 reads (61%) | catalogued as COSV53959886; called by muse, mutect2, varscan2
- LIFR | c.590A>T p.K197I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV54699174; called by muse, mutect2, varscan2
- LILRA5 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56645106; called by muse, mutect2, varscan2
- LILRA6 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54446003; called by mutect2, varscan2
- LIPF | c.961-1G>T p.X321_splice | Splice Site (SNP) | VAF 59/157 reads (38%) | catalogued as COSV53286200; called by muse, mutect2, varscan2
- LPA | c.3553A>C p.T1185P | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV60311212; called by muse, mutect2, varscan2
- LRP1B | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as COSV63341662, COSV63341982, COSV63341998; called by muse, mutect2, varscan2
- LRP2 | c.11785A>T p.T3929S | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV55572507; called by muse, mutect2, varscan2
- LRRIQ1 | c.1357A>G p.R453G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV67837891; called by muse, mutect2, varscan2
- LRRTM1 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54446377; called by muse, mutect2, varscan2
- LSAMP | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61309506; called by muse, mutect2, varscan2
- LVRN | c.1864A>T p.T622S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV63498301; called by muse, mutect2, varscan2
- MAGED2 | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as COSV54499278; called by muse, mutect2, varscan2
- MAP4K1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV50263741, COSV50264542; called by muse, mutect2, varscan2
- MARCHF11 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV60134434, COSV60136295; called by muse, mutect2, varscan2
- MARF1 | c.4595G>T p.S1532I | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV60028682; called by muse, mutect2, varscan2
- MB21D2 | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV66665863; called by muse, mutect2, varscan2
- MDH1B | c.1209G>C p.L403F | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV65591652; called by muse, mutect2, varscan2
- MDN1 | c.13462G>C p.D4488H | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1421584859, COSV65529719; called by muse, mutect2, varscan2
- MDP1 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51661799; called by muse, mutect2, varscan2
- MED12 | c.1650G>C p.K550N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61354766, COSV61356627; called by muse, mutect2, varscan2
- MED13L | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.281); catalogued as COSV56129484; called by muse, mutect2
- MEFV | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV54823775, COSV54827273; called by muse, mutect2, varscan2
- MFSD6 | c.303C>G p.S101R | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV55625157; called by muse, mutect2, varscan2
- MGA | c.27G>T p.L9F | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54962386; called by muse, mutect2, varscan2
- MGA | c.5324G>T p.R1775I (on ENST00000219905 / NM_001164273.1; = p.R1566I on NM_001080541.2) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54962394; called by muse, mutect2, varscan2
- MGAT3 | c.10A>T p.R4* | Nonsense Mutation (SNP) | VAF 54/173 reads (31%) | catalogued as COSV57868253; called by muse, mutect2, varscan2
- MICALL1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV53243264; called by muse, mutect2, varscan2
- MID1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV58192518, COSV58199550; called by muse, mutect2
- MID1 | c.105C>A p.H35Q | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.407); catalogued as COSV58199561; called by muse, mutect2
- MIOS | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV60770519; called by muse, mutect2, varscan2
- MIPEP | c.453-1G>T p.X151_splice | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as COSV66301835; called by muse, mutect2, varscan2
- MIXL1 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64729413; called by muse, mutect2, varscan2
- MMP12 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs1555009887, COSV58261366; called by muse, mutect2, varscan2
- MMRN1 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV53342216; called by muse, mutect2, varscan2
- MPRIP | c.1342A>T p.R448* | Nonsense Mutation (SNP) | VAF 126/163 reads (77%) | catalogued as COSV100506113; called by muse, mutect2, varscan2
- MROH2B | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 41/241 reads (17%) | catalogued as COSV68189178; called by muse, mutect2, varscan2
- MSRA | c.437-1G>A p.X146_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as rs1167617260, COSV57810857; called by muse, mutect2, varscan2
- MTCL1 | c.3910C>T p.R1304C (on ENST00000306329 / NM_001378206.1; = p.R985C on NM_015210.4) | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1240061406, COSV60411478; called by muse, mutect2, varscan2
- MTTP | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs137956833, COSV55509565; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.40489C>A p.H13497N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.931); catalogued as COSV66696143; called by muse, mutect2, varscan2
- MUC16 | c.27893A>G p.E9298G | Missense Mutation (SNP) | VAF 96/153 reads (63%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV67491240; called by muse, mutect2, varscan2
- MUC5AC | c.15650C>T p.P5217L | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs749148814, COSV100611578, COSV100611641; called by muse, mutect2, varscan2
- MXRA8 | c.1214T>A p.I405N | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58511720; called by muse, mutect2, varscan2
- MYCBP2 | c.7947C>A p.S2649R (on ENST00000357337; = p.S2687R on NM_015057.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV62037935; called by muse, mutect2, varscan2
- MYF6 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57353210; called by muse, mutect2, varscan2
- MYH6 | c.2354G>T p.R785L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62454259; called by muse, mutect2, varscan2
- MYH8 | c.898C>G p.L300V | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV67959135, COSV67971872; called by muse, mutect2, varscan2
- MYLIP | c.814C>G p.H272D | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62767609; called by muse, mutect2, varscan2
- MYO3A | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV56347678; called by muse, mutect2, varscan2
- MYT1 | c.673G>T p.V225F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV60512907; called by muse, mutect2, varscan2
- MYT1L | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV67731735; called by muse, mutect2, varscan2
- MZF1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV53043170; called by muse, mutect2, varscan2
- MZF1 | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53043179; called by muse, mutect2, varscan2
- NAP1L3 | c.18T>A p.F6L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59077547; called by muse, mutect2, varscan2
- NAPB | c.565G>T p.G189W | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63326242; called by muse, mutect2
- NAV3 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated, low confidence (0.66); PolyPhen probably damaging (0.974); catalogued as COSV57092482; called by muse, mutect2, varscan2
- NAV3 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV57110185; called by muse, mutect2
- NAV3 | c.2120A>T p.Q707L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57110207; called by muse, mutect2, varscan2
- NAV3 | c.3041-1G>T p.X1014_splice | Splice Site (SNP) | VAF 50/174 reads (29%) | catalogued as COSV57103301; called by muse, mutect2, varscan2
- NBAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.326); catalogued as rs1424478817, COSV55736848; called by muse, mutect2, varscan2
- NCDN | c.470A>T p.Q157L | Missense Mutation (SNP) | VAF 82/146 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as COSV57850270; called by muse, mutect2, varscan2
- NDST4 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.734); catalogued as COSV52120487, COSV52136342; called by muse, mutect2, varscan2
- NDUFA4 | c.42+1G>A p.X14_splice | Splice Site (SNP) | VAF 95/156 reads (61%) | catalogued as CS135836, COSV100292881; called by muse, mutect2, varscan2
- NEBL | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV65805539; called by muse, mutect2, varscan2
- NES | c.3598C>T p.P1200S | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1373731571, COSV63962005; called by muse, mutect2, varscan2
- NEUROD4 | c.704C>A p.S235* | Nonsense Mutation (SNP) | VAF 25/144 reads (17%) | catalogued as COSV54472486, COSV54473978; called by muse, mutect2, varscan2
- NFAM1 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV61196355; called by muse, mutect2, varscan2
- NFS1 | c.792G>T p.G264= | Splice Region (SNP) | VAF 12/38 reads (32%) | catalogued as rs750700576, COSV65054276; called by muse, mutect2
- NID1 | c.1159C>A p.R387S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV51628498; called by muse, mutect2, varscan2
- NIPBL | c.6639G>C p.K2213N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56964958; called by muse, mutect2
- NLGN4X | c.1560C>A p.S520R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52018343, COSV52028153; called by muse, mutect2, varscan2
- NLRC5 | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV52662662; called by muse, mutect2, varscan2
- NLRP13 | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61623922; called by muse, mutect2, varscan2
- NLRP3 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 71/181 reads (39%) | catalogued as COSV60230553; called by muse, mutect2, varscan2
- NOL6 | c.2764A>T p.N922Y | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53045391; called by muse, mutect2, varscan2
- NOLC1 | c.724-1G>T p.X242_splice | Splice Site (SNP) | VAF 69/140 reads (49%) | catalogued as COSV64181078; called by muse, mutect2, varscan2
- NOP2 | c.959G>T p.R320L (on ENST00000322166 / NM_001258308.2; = p.R316L on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100445195; called by muse, mutect2
- NOS1 | c.2924G>T p.R975L | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57612982, COSV57620960; called by muse, mutect2, varscan2
- NPBWR2 | c.446C>A p.T149N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV63900557; called by muse, mutect2, varscan2
- NPC1L1 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV56929960; called by muse, mutect2, varscan2
- NR0B1 | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV66764774; called by muse, mutect2, varscan2
- NRXN1 | c.3757A>G p.I1253V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs754289531, COSV60520739; called by muse, mutect2, varscan2
- NUGGC | c.250T>A p.Y84N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58438866; called by muse, mutect2, varscan2
- NUP153 | c.2503G>C p.V835L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50463747; called by muse, mutect2, varscan2
- NUP210 | c.2522-1G>T p.X841_splice | Splice Site (SNP) | VAF 38/67 reads (57%) | catalogued as COSV54413420; called by muse, mutect2, varscan2
- NUSAP1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV52973209; called by muse, mutect2, varscan2
- OLIG3 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 70/168 reads (42%) | catalogued as COSV62989133; called by muse, varscan2
- OPN5 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 28/119 reads (24%) | catalogued as COSV55247464, COSV99789700; called by muse, mutect2, varscan2
- OR10A5 | c.391T>A p.L131M | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55055618; called by muse, mutect2, varscan2
- OR10G2 | c.349T>A p.C117S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV73390463; called by muse, mutect2, varscan2
- OR10W1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); catalogued as COSV67720639; called by muse, mutect2, varscan2
- OR11G2 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV62133038, COSV62133059; called by muse, mutect2, varscan2
- OR2D3 | c.686T>A p.L229Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1212322850, COSV53494817; called by muse, mutect2, varscan2
- OR2G6 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV58575755, COSV58576087; called by muse, mutect2, varscan2
- OR2M4 | c.73A>T p.T25S | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV60709612; called by muse, mutect2, varscan2
- OR2T10 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57898308; called by muse, mutect2, varscan2
- OR2T11 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV58186224; called by muse, mutect2, varscan2
- OR2T33 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as COSV58814403, COSV58817745; called by muse, mutect2, varscan2
- OR4C6 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV58606122; called by muse, mutect2, varscan2
- OR4D5 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58309328, COSV58309927; called by muse, mutect2, varscan2
- OR51T1 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100434430, COSV59027882; called by muse, mutect2, varscan2
- OR52B6 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61448270; called by muse, mutect2, varscan2
- OR5AS1 | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV57980709, COSV57980768, COSV57983116; called by muse, mutect2, varscan2
- OR5D13 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV62335227; called by muse, mutect2, varscan2
- OR5D16 | c.879T>A p.S293R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65722529; called by muse, mutect2, varscan2
- OR5K1 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60305284; called by muse, mutect2, varscan2
- OR5L1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV61735316, COSV99081997; called by muse, mutect2, varscan2
- OR5R1 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV56571488; called by muse, mutect2, varscan2
- OR6K2 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62743276, COSV62743573; called by muse, mutect2, varscan2
- OTOGL | c.2087G>T p.G696V (on ENST00000547103; = p.G687V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/278 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.144); catalogued as COSV101509492; called by muse, mutect2, varscan2
- OTUD6B | c.509A>T p.K170M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as COSV53444320; called by muse, mutect2, varscan2
- OXR1 | c.849G>T p.K283N (on ENST00000442977 / NM_001198532.1; = p.K282N on NM_018002.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV56335915; called by muse, mutect2, varscan2
- P2RY2 | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV60777708; called by muse, mutect2, varscan2
- PABPC5 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57042440, COSV57043099; called by muse, mutect2, varscan2
- PAGR1 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1043266857, COSV56191443; called by muse, mutect2
- PALD1 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as rs767240221, COSV54970450, COSV54971844, COSV54976023; called by muse, mutect2, varscan2
- PCDH10 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52094374; called by muse, mutect2, varscan2
- PCDH10 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52103302; called by muse, mutect2, varscan2
- PCDH17 | c.847A>T p.S283C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV64978814; called by muse, mutect2, varscan2
- PCDH17 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 38/184 reads (21%) | catalogued as COSV64978820; called by muse, mutect2, varscan2
- PCDH8 | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778924290, COSV58812913, COSV58814995; called by muse, mutect2, varscan2
- PCDHA1 | c.1573C>A p.H525N | Missense Mutation (SNP) | VAF 99/156 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as COSV65376808; called by muse, varscan2
- PCDHB12 | c.1491C>A p.H497Q | Missense Mutation (SNP) | VAF 91/157 reads (58%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.034); catalogued as COSV53400719; called by muse, mutect2, varscan2
- PCDHB12 | c.1721A>T p.E574V | Missense Mutation (SNP) | VAF 106/175 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53400730; called by muse, mutect2, varscan2
- PCDHB14 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53391169; called by muse, mutect2, varscan2
- PCDHB6 | c.1797G>T p.W599C | Missense Mutation (SNP) | VAF 87/152 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV50726595; called by muse, mutect2, varscan2
- PCDHB9 | c.1685T>A p.L562Q | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53383486; called by muse, mutect2, varscan2
- PCDHGA10 | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54025338; called by muse, mutect2, varscan2
- PCDHGB2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1306730531, COSV54025302; called by muse, mutect2, varscan2
- PCNX1 | c.6836G>T p.G2279V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53101341; called by mutect2, varscan2
- PDE1A | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as COSV59535412; called by muse, mutect2, varscan2
- PDE1B | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54492049; called by muse, mutect2, varscan2
- PDE6C | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65117568; called by muse, mutect2
- PDIA4 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53726710; called by muse, mutect2, varscan2
- PDLIM7 | c.901T>A p.Y301N | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62883798; called by muse, mutect2, varscan2
- PEG3 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV55646195; called by muse, mutect2, varscan2
- PGAP4 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 51/81 reads (63%) | catalogued as COSV66387897, COSV66388361; called by muse, mutect2, varscan2
- PGAP6 | c.1967G>C p.W656S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51742289; called by muse, varscan2
- PGLYRP2 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99484258, COSV99484290; called by muse, mutect2, varscan2
- PGM2L1 | c.1354A>G p.S452G | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV53349359; called by muse, mutect2, varscan2
- PGM5 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as rs782530011, COSV67169067; called by muse, mutect2, varscan2
- PHKB | c.708G>T p.S236= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV54516537, COSV54533171; called by muse, mutect2, varscan2
- PITPNC1 | c.197G>T p.S66I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV55457819; called by muse, mutect2
- PKHD1L1 | c.4354G>T p.G1452C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65752156; called by muse, mutect2, varscan2
- PLA2G2A | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1557701713, COSV64287611; called by muse, mutect2, varscan2
- PLB1 | c.2152A>T p.R718W | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV59834813; called by muse, mutect2, varscan2
- PLPP4 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64829597; called by muse, mutect2, varscan2
- PMFBP1 | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 71/105 reads (68%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV52831395; called by muse, mutect2, varscan2
- PML | c.1262A>T p.E421V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV51453771; called by muse, mutect2, varscan2
- PNPLA6 | c.2638G>T p.G880W (on ENST00000414982 / NM_001166111.2; = p.G832W on NM_006702.5) | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55384455; called by muse, mutect2, varscan2
- POGLUT2 | c.1495A>T p.K499* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV65683573; called by muse, mutect2, varscan2
- PORCN | c.968G>T p.R323L (on ENST00000326194 / NM_203475.3; = p.R312L on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV58227146; called by muse, mutect2, varscan2
- POTEE | c.2731G>A p.D911N | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as COSV58243380; called by muse, mutect2
- POTEM | c.177C>A p.S59R | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as COSV69153813; called by muse, varscan2
- PPARGC1A | c.568A>G p.S190G | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV53533239, COSV99337980; called by muse, mutect2, varscan2
- PPARGC1B | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58530499; called by muse, mutect2, varscan2
- PPP1R18 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs755337750, COSV51298520; called by muse, mutect2, varscan2
- PPP2R3B | c.1086-2A>G p.X362_splice | Splice Site (SNP) | VAF 61/213 reads (29%) | catalogued as COSV66814351; called by muse, mutect2, varscan2
- PRDX3 | c.93G>T p.R31S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.035); catalogued as rs754054596, COSV100045438; called by muse, mutect2, varscan2
- PRDX3 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.268); catalogued as COSV100045443; called by muse, mutect2, varscan2
- PREX1 | c.1996A>T p.R666W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64256477; called by muse, mutect2, varscan2
- PRKD2 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52189424; called by muse, mutect2
- PRPF4B | c.2317A>T p.N773Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61785701; called by muse, mutect2, varscan2
- PRRC2B | c.4236G>T p.E1412D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100622190, COSV61942686; called by muse, mutect2, varscan2
- PRRC2C | c.3638G>T p.G1213V (on ENST00000367742; = p.G1211V on NM_015172.4) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV58912535; called by muse, mutect2, varscan2
- PSG1 | c.1225A>G p.M409V | Missense Mutation (SNP) | VAF 163/457 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372978242, COSV54956906; called by muse, mutect2, varscan2
- PSMA8 | c.297C>G p.C99W | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57604957; called by muse, mutect2, varscan2
- PSMD1 | c.575A>T p.Q192L | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748201534, COSV58083273; called by muse, mutect2, varscan2
- PTDSS1 | c.674G>A p.C225Y | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61266483; called by muse, mutect2, varscan2
- PTGER3 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60691240; called by muse, mutect2, varscan2
- PTPN13 | c.6686G>T p.C2229F (on ENST00000411767 / NM_080683.3; = p.C2210F on NM_006264.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57416740; called by muse, mutect2, varscan2
- PTPRR | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51746751; called by muse, mutect2, varscan2
- PURG | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53306970; called by muse, mutect2, varscan2
- PURG | c.447G>T p.R149S | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.042); catalogued as COSV53306979; called by muse, mutect2, varscan2
- PUS7L | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.099); catalogued as rs1176981174, COSV61262924; called by muse, mutect2, varscan2
- PZP | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54358815, COSV54369584; called by muse, mutect2, varscan2
- R3HCC1L | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as rs1186347783, COSV54405079; called by muse, mutect2, varscan2
- RAB8B | c.324+1G>A p.X108_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | catalogued as COSV58491153, COSV58491193; called by muse, mutect2, varscan2
- RAF1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV52583714; called by muse, mutect2, varscan2
- RAMAC | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100417963; called by muse, varscan2
- RAPGEF6 | c.2114G>T p.S705I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57255163; called by muse, mutect2, varscan2
- RASD2 | c.617T>A p.V206E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV53353564; called by muse, mutect2, varscan2
- RBM10 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV61312036; called by muse, mutect2, varscan2
- RBM10 | c.2687G>T p.G896V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61312042; called by muse, mutect2, varscan2
- RBMS3 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as COSV56167006; called by muse, mutect2, varscan2
- REG1B | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs546205053, COSV59307698; called by muse, mutect2, varscan2
- REG3G | c.402del p.N136Ifs*6 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | catalogued as COSV99709710; called by pindel, varscan2
- REM1 | c.721C>A p.R241S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52427640, COSV52429927; called by muse, mutect2, varscan2
- RGS7 | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV58559274; called by muse, mutect2, varscan2
- RHAG | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs1411229670, COSV57704420; called by muse, mutect2, varscan2
- RIMS3 | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV65505387; called by muse, mutect2, varscan2
- RIPOR1 | c.1628C>T p.S543L (on ENST00000379312 / NM_001193522.2; = p.S539L on NM_024519.4) | Missense Mutation (SNP) | VAF 129/650 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV50260023; called by muse, mutect2, varscan2
- RIPOR1 | c.2093C>G p.S698* (on ENST00000379312 / NM_001193522.2; = p.S694* on NM_024519.4) | Nonsense Mutation (SNP) | VAF 91/592 reads (15%) | catalogued as COSV50260319; called by muse, mutect2, varscan2
- RIPOR3 | c.2157C>G p.F719L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV50403074; called by muse, mutect2, varscan2
- RNF24 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1253522157, COSV60192894; called by muse, mutect2, varscan2
- RPS6KA4 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV53706527; called by muse, mutect2, varscan2
- RTN1 | c.1704G>T p.K568N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV50746117, COSV99956612; called by muse, mutect2, varscan2
- RTP2 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64079446; called by muse, mutect2, varscan2
- SBF2 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV56310610; called by muse, mutect2
- SBNO2 | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs764699629, COSV62323407; called by muse, mutect2, varscan2
- SCAPER | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV57752894; called by muse, mutect2, varscan2
- SCG3 | c.888A>T p.K296N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV55023128; called by muse, mutect2, varscan2
- SCN5A | c.5393G>A p.W1798* (on ENST00000333535 / NM_198056.3; = p.W1797* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs879050352, CM097688, COSV61115512, COSV61139924; called by muse, mutect2, varscan2
- SCN7A | c.4343G>A p.W1448* | Nonsense Mutation (SNP) | VAF 104/189 reads (55%) | catalogued as COSV69274481; called by muse, mutect2, varscan2
- SCUBE1 | c.845-1G>C p.X282_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV62616017; called by muse, mutect2, varscan2
- SEMA4F | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100335944, COSV60285143; called by muse, mutect2, varscan2
- SEMA5A | c.2976C>A p.Y992* | Nonsense Mutation (SNP) | VAF 69/314 reads (22%) | catalogued as COSV66804617; called by muse, mutect2, varscan2
- SEMA5A | c.2648T>A p.L883Q | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); catalogued as COSV66804624; called by muse, mutect2, varscan2
- SEMA6D | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.177); catalogued as COSV60383419; called by muse, mutect2, varscan2
- SEPTIN14 | c.848A>T p.K283M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66431055; called by muse, mutect2, varscan2
- SERGEF | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56387167; called by muse, mutect2, varscan2
- SERPINB3 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.812); catalogued as COSV52194020; called by muse, mutect2, varscan2
- SERPINB4 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61986159; called by muse, mutect2, varscan2
- SERPINI2 | c.620del p.N207Mfs*9 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as COSV52987999; called by mutect2, pindel, varscan2
- SFSWAP | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV104377397, COSV55525595; called by muse, mutect2, varscan2
- SH2B1 | c.1511C>G p.T504R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV59466641; called by muse, mutect2, varscan2
- SHOX2 | c.673G>T p.V225L (on ENST00000441443 / NM_006884.3; = p.V249L on NM_003030.4) | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs147753879, COSV67464724; called by muse, mutect2, varscan2
- SIDT1 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs367865105, COSV53506355; called by muse, mutect2, varscan2
- SIGLEC9 | c.8T>A p.L3Q | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV51588001; called by muse, mutect2, varscan2
- SIPA1L1 | c.4925G>A p.G1642E | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV62168795, COSV62173396; called by muse, mutect2, varscan2
- SIPA1L1 | c.5401A>G p.I1801V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.847); catalogued as COSV62173399; called by muse, mutect2, varscan2
- SKIL | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 100/139 reads (72%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52062873; called by muse, mutect2, varscan2
- SLC2A14 | c.997A>T p.I333F | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1278727616, COSV61588492; called by muse, mutect2, varscan2
- SLC35G1 | c.844G>T p.G282W (on ENST00000427197 / NM_001134658.3; = p.G281W on NM_153226.4) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65055058, COSV65055726; called by muse, mutect2, varscan2
- SLC38A5 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58335500; called by muse, mutect2
- SLC38A5 | c.1094T>G p.L365R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58335510; called by muse, mutect2, varscan2
- SLC6A18 | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV57254238; called by muse, mutect2, varscan2
- SLC8A1 | c.2234G>T p.R745I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60470975, COSV60495332; called by muse, varscan2
- SLC8A3 | c.2190C>A p.Y730* (on ENST00000381269 / NM_183002.3; = p.Y728* on NM_033262.4) | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV53687621; called by muse, mutect2, varscan2
- SLITRK1 | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.921); catalogued as COSV101000053; called by muse, mutect2, varscan2
- SMAD1 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57473352; called by muse, mutect2, varscan2
- SMC4 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as COSV61007772; called by muse, mutect2, varscan2
- SMIM29 | c.92G>T p.R31L (on ENST00000394990 / NM_001008704.3; = p.R51L on NM_178508.5) | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV58988220, COSV58988903; called by muse, mutect2, varscan2
- SMO | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50842176; called by muse, mutect2, varscan2
- SMOX | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV53864368, COSV53868058; called by muse, mutect2, varscan2
- SNTG1 | c.977G>T p.W326L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.953); catalogued as COSV52470140; called by muse, mutect2
- SORCS1 | c.2376C>G p.C792W | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53902559; called by muse, mutect2, varscan2
- SOST | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV57012917; called by muse, mutect2, varscan2
- SOST | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100059784; called by muse, mutect2, varscan2
- SPATA16 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs773869551, COSV63532924; called by muse, mutect2
- SPEF2 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56800305; called by muse, mutect2, varscan2
- SPESP1 | c.743del p.P248Qfs*14 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as COSV52990318; called by mutect2, pindel, varscan2
- SPRN | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV58155178; called by muse, mutect2, varscan2
- STARD13 | c.3153C>A p.D1051E (on ENST00000336934 / NM_001243476.3; = p.D933E on NM_052851.3) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55236203; called by muse, mutect2
- SUPT20HL1 | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs370107923; called by muse, mutect2, varscan2
- SUPT20HL2 | c.2310G>T p.Q770H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs766333160; called by muse, mutect2, varscan2
- SYN1 | c.821A>G p.H274R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV54483898; called by muse, mutect2
- SYNE1 | c.12078G>C p.R4026S (on ENST00000367255 / NM_182961.4; = p.R3955S on NM_033071.3) | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55092852, COSV99557431; called by muse, mutect2, varscan2
- SYNE2 | c.11402T>A p.I3801K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV59968619; called by muse, mutect2, varscan2
- TAF5L | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51089827; called by muse, mutect2, varscan2
- TANC2 | c.2782G>T p.A928S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.393); catalogued as COSV67341095; called by muse, mutect2, varscan2
- TASP1 | c.976A>T p.K326* | Nonsense Mutation (SNP) | VAF 16/193 reads (8%) | catalogued as COSV61815753; called by muse, mutect2
- TBC1D4 | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV66491915; called by muse, mutect2, varscan2
- TBCD | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 121/284 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1382474660, COSV62797214, COSV62807303; called by muse, mutect2, varscan2
- TBX20 | c.1124T>A p.I375K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as COSV68785672; called by muse, mutect2, varscan2
- TCERG1L | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.226); catalogued as COSV64056784; called by muse, mutect2, varscan2
- TCHHL1 | c.1179G>C p.E393D | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs866814465, COSV64287508; called by muse, mutect2, varscan2
- TDRD1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs1564935642, COSV52595846; called by muse, mutect2, varscan2
- TEC | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as COSV67406318; called by muse, mutect2, varscan2
- TECRL | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1409531996, COSV101169360; called by muse, mutect2, varscan2
- TECRL | c.591C>A p.Y197* | Nonsense Mutation (SNP) | VAF 38/78 reads (49%) | catalogued as COSV101169362; called by muse, mutect2, varscan2
- TEKT1 | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 124/165 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV58623808, COSV58624943; called by muse, mutect2, varscan2
- TENM3 | c.1935G>T p.K645N | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV69318371; called by muse, mutect2, varscan2
- TFF2 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52297205; called by muse, mutect2, varscan2
- TG | c.6097C>A p.Q2033K | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV55093087; called by muse, mutect2, varscan2
- TGFBR3 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV53030913; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1526G>T p.W509L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV51516121; called by muse, mutect2
- THRB | c.1145-2A>G p.X382_splice | Splice Site (SNP) | VAF 49/82 reads (60%) | catalogued as COSV99769757; called by muse, mutect2, varscan2
- TJP2 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV55269044; called by muse, mutect2, varscan2
- TKTL1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV54214891; called by muse, mutect2, varscan2
- TLCD4 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV64633466; called by muse, mutect2, varscan2
- TLL2 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV63572264, COSV63575589; called by muse, mutect2, varscan2
- TLN2 | c.3359-2A>C p.X1120_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | catalogued as COSV60895314; called by muse, mutect2, varscan2
- TM6SF1 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV51946326; called by muse, mutect2, varscan2
- TMC3 | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.786); catalogued as COSV63924572; called by muse, mutect2, varscan2
- TMEM260 | c.1643T>G p.V548G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55102408; called by muse, mutect2, varscan2
- TMEM63A | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as rs200544450, COSV64762594, COSV64764092; called by muse, varscan2
- TMPO | c.2081A>T p.H694L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV99702195; called by muse, mutect2, varscan2
- TMTC1 | c.2506A>T p.K836* (on ENST00000539277 / NM_001193451.2; = p.K728* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 103/274 reads (38%) | catalogued as COSV55492877; called by muse, mutect2, varscan2
- TMTC2 | c.2388G>T p.Q796H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.251); catalogued as COSV58282773; called by muse, mutect2, varscan2
- TNNI3 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV61279349; called by muse, mutect2, varscan2
- TNRC6B | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57307135; called by muse, mutect2, varscan2
- TPH2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV61590489, COSV61591680, COSV61594179; called by muse, mutect2
- TRAIP | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58916542; called by muse, varscan2
- TRAPPC11 | c.1598G>T p.R533L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV58216451, COSV58219075; called by muse, mutect2, varscan2
- TRERF1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 104/171 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.097); catalogued as COSV61677799; called by muse, mutect2, varscan2
- TRIM26 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV70983562; called by muse, mutect2, varscan2
- TRIP6 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV51936801; called by muse, mutect2, varscan2
- TRPM1 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.326); catalogued as COSV56641782; called by muse, mutect2, varscan2
- TRPM8 | c.2301dup p.E768Rfs*14 | Frame Shift Ins (INS) | VAF 104/549 reads (19%) | catalogued as rs770879940; called by mutect2, varscan2
- TSHR | c.799T>A p.L267M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV53330883; called by muse, mutect2, varscan2
- TSKS | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.66); PolyPhen benign (0.269); catalogued as COSV55879024; called by muse, mutect2, varscan2
- TSPOAP1 | c.4694G>T p.R1565L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as COSV52117096; called by muse, mutect2, varscan2
- TSPYL6 | c.1076T>A p.L359H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV57819873; called by muse, mutect2, varscan2
- TTC7B | c.2435G>T p.G812V | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60638882; called by muse, mutect2, varscan2
- TTN | c.80053C>G p.R26685G (on ENST00000591111; = p.R19261G on NM_003319.4) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | PolyPhen possibly damaging (0.736); catalogued as rs749633038, COSV60075667, COSV60324430; called by muse, mutect2, varscan2
- TTN | c.23867T>C p.V7956A (on ENST00000591111; = p.V7029A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/82 reads (54%) | PolyPhen benign (0.003); catalogued as COSV60324528; called by muse, mutect2, varscan2
- TUBB | c.1076G>C p.R359P | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV58358309; called by muse, mutect2, varscan2
- TUFM | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV57949781; called by muse, mutect2, varscan2
- UBA1 | c.1762T>C p.C588R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60115314; called by muse, mutect2, varscan2
- UBR4 | c.14761C>T p.P4921S | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1184149144, COSV64398687; called by muse, mutect2, varscan2
- UBXN4 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV55637878; called by muse, mutect2, varscan2
- UHRF2 | c.2267G>C p.C756S | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52791961, COSV52796120; called by muse, mutect2, varscan2
- UIMC1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 98/173 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65895066; called by muse, mutect2, varscan2
- UNC13C | c.6072G>C p.L2024F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52920963; called by muse, mutect2
- UNC5D | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV54788683, COSV54832994, COSV99779546; called by muse, mutect2, varscan2
- UNC5D | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV54833013; called by muse, mutect2, varscan2
- UNC79 | c.7660G>C p.V2554L (on ENST00000393151 / NM_001346218.2; = p.V2377L on NM_020818.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56408879; called by muse, mutect2, varscan2
- USH1C | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as COSV50014969; called by muse, mutect2, varscan2
- USH2A | c.9940G>A p.V3314M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV56371827, COSV56430319; called by muse, mutect2, varscan2
- USH2A | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1367873656, COSV56403131; called by muse, mutect2, varscan2
- USHBP1 | c.25del p.R9Efs*39 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as COSV53102333; called by mutect2, pindel, varscan2
- USP29 | c.1266C>A p.C422* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as COSV99518615; called by muse, mutect2, varscan2
- USP29 | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99518617; called by muse, varscan2
- USP43 | c.2656G>T p.G886C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as COSV53306713; called by muse, mutect2, varscan2
- USP6 | c.3270G>T p.W1090C | Missense Mutation (SNP) | VAF 162/201 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51478345, COSV51495571; called by muse, mutect2, varscan2
- UXT | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV60040007; called by muse, mutect2, varscan2
- VCAM1 | c.1421T>C p.I474T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1482153192, COSV54120316; called by muse, mutect2, varscan2
- VDAC2 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV53687612; called by muse, mutect2, varscan2
- VPS11 | c.129G>T p.R43S (on ENST00000620429; = p.R587S on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT tolerated (0.36); PolyPhen benign (0.312); catalogued as COSV56186916; called by muse, mutect2, varscan2
- VPS13A | c.6973A>T p.I2325L | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100652827, COSV62438417; called by muse, mutect2, varscan2
- VPS13D | c.7249C>T p.P2417S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as COSV50679450; called by muse, mutect2, varscan2
- VPS13D | c.7609C>T p.Q2537* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV50679561; called by muse, mutect2, varscan2
- VWCE | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV57115297; called by muse, mutect2, varscan2
- WDFY3 | c.6320A>T p.H2107L | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV55713021; called by muse, mutect2, varscan2
- WDR33 | c.1306A>T p.N436Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV59255225; called by muse, mutect2, varscan2
- WDR49 | c.1903C>A p.P635T (on ENST00000308378 / NM_001366158.1; = p.P976T on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs753705042, COSV57704772, COSV57717281; called by muse, mutect2, varscan2
- WDR72 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV64753650; called by muse, mutect2, varscan2
- WDR86 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs573246750, COSV100561363, COSV57838515, COSV57843527; called by muse, mutect2, varscan2
- XCR1 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as rs752445557, COSV58570707; called by muse, mutect2, varscan2
- XKR7 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs1225688451, COSV73813446; called by muse, mutect2, varscan2
- YY2 | c.777C>G p.S259R | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV63412405; called by muse, mutect2, varscan2
- ZBED9 | c.2950G>T p.V984L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV71729755; called by muse, mutect2, varscan2
- ZBTB20 | c.895G>T p.E299* (on ENST00000474710 / NM_001164342.2; = p.E226* on NM_015642.6 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 78/124 reads (63%) | catalogued as COSV61867170; called by muse, mutect2, varscan2
- ZEB2 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57965637; called by muse, varscan2
- ZEB2 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57965648; called by muse, varscan2
- ZFAND6 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1164259359, COSV55711796; called by muse, mutect2, varscan2
- ZFAT | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64746110; called by muse, mutect2, varscan2
- ZFHX4 | c.10633C>A p.P3545T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV51494272, COSV51498611; called by muse, mutect2, varscan2
- ZFYVE26 | c.4214A>G p.H1405R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV61333288; called by muse, mutect2, varscan2
- ZHX2 | c.562A>T p.K188* | Nonsense Mutation (SNP) | VAF 38/159 reads (24%) | catalogued as COSV58717042; called by muse, mutect2, varscan2
- ZMIZ1 | c.1645A>C p.S549R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV57903359; called by muse, mutect2, varscan2
- ZNF195 | c.789G>C p.Q263H (on ENST00000399602 / NM_001130520.3; = p.Q191H on NM_007152.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50007700; called by muse, mutect2, varscan2
- ZNF215 | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV53494821; called by muse, mutect2, varscan2
- ZNF366 | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV59218855; called by muse, mutect2, varscan2
- ZNF394 | c.996C>A p.H332Q | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs911125493, COSV61794451; called by muse, mutect2, varscan2
- ZNF41 | c.1358A>T p.H453L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV57445138; called by muse, mutect2, varscan2
- ZNF470 | c.955A>G p.K319E | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV57970618; called by muse, mutect2, varscan2
- ZNF536 | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 79/139 reads (57%) | catalogued as COSV62819518, COSV62833435; called by muse, mutect2, varscan2
- ZNF549 | c.1700G>T p.R567I (on ENST00000376233 / NM_001199295.2; = p.R554I on NM_153263.2) | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV53727680; called by muse, mutect2, varscan2
- ZNF554 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57886941; called by muse, mutect2, varscan2
- ZNF606 | c.2300G>A p.S767N | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58706951, COSV58707930; called by muse, mutect2, varscan2
- ZNF616 | c.2179G>T p.G727W | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV57513186; called by muse, mutect2, varscan2
- ZNF648 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60572664; called by muse, mutect2, varscan2
- ZNF689 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV54910051; called by muse, mutect2
- ZNF708 | c.701A>T p.N234I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.547); catalogued as COSV63608740; called by muse, mutect2, varscan2
- ZNF773 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV56590339; called by muse, mutect2, varscan2
- ZP4 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV63913396; called by muse, mutect2, varscan2
- ZSCAN18 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 7/9 reads (78%) | catalogued as COSV53737001; called by muse, mutect2, varscan2
- ZSCAN20 | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63684453; called by muse, mutect2, varscan2
- ZSWIM8 | c.2255G>T p.G752V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); catalogued as COSV67134623; called by muse, mutect2, varscan2
- ZZEF1 | c.2058G>T p.Q686H | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV67560105; called by muse, mutect2, varscan2
- ADAMTS12 | c.871dup p.I291Nfs*30 | Frame Shift Ins (INS) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- AKAP6 | c.4195del p.D1399Tfs*11 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel*, varscan2
- CCL4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- EPAS1 | c.2050del p.A684Qfs*12 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- FAT3 | c.7514_7535del p.V2505Efs*4 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | called by mutect2, pindel
- GKN1 | c.176_178dup p.S59dup | In Frame Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- IGKV1D-17 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KIF19 | c.2933dup p.G979Wfs*20 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.661_662delinsC p.G221Pfs*5 | Frame Shift Del (DEL) | VAF 98/371 reads (26%) | called by mutect2*, pindel, varscan2*
- KRTAP5-3 | c.139del p.C47Afs*219 | Frame Shift Del (DEL) | VAF 71/307 reads (23%) | called by mutect2, pindel, varscan2
- LILRB3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MRPL28 | c.447del p.K150Rfs*12 | Frame Shift Del (DEL) | VAF 34/121 reads (28%) | called by mutect2, pindel, varscan2
- MUC2 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated, low confidence (0.26); called by muse, mutect2, varscan2
- PCDH15 | c.4739del p.L1580Yfs*5 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- POTEF | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); called by mutect2, varscan2
- RPRD1B | c.216del p.G74Dfs*31 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- RSPH6A | c.1992del p.I665Ffs*14 | Frame Shift Del (DEL) | VAF 196/400 reads (49%) | called by pindel, varscan2
- SLC1A3 | c.698del p.P233Qfs*6 | Frame Shift Del (DEL) | VAF 15/143 reads (10%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TCF23 | c.500del p.G167Afs*104 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- TOX2 | c.589del p.H197Tfs*142 (on ENST00000358131 / NM_001098798.2; = p.H146Tfs*120 on NM_032883.3) | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- TPTE | c.795+1G>C p.X265_splice (on ENST00000618007 / NM_199261.4; = p.X247_splice on NM_199259.4) | Splice Site (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2, varscan2
- TRBV27 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRIM11 | c.1206del p.R402Sfs*51 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- VCX3A | c.284T>A p.V95E | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, varscan2
- VPS33A | c.1652_1653delinsT p.G551Vfs*3 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | called by pindel, varscan2*
- ABCA1 | c.2070C>T p.L690= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV66070225; called by muse, mutect2, varscan2
- ABCA8 | c.639C>A p.S213= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV52211357; called by muse, mutect2, varscan2
- ACSBG1 | c.2040G>A p.Q680= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV51910387; called by muse, mutect2, varscan2
- ADGRA2 | c.576G>A p.L192= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV59447078; called by muse, mutect2, varscan2
- ADGRL3 | c.2820C>A p.V940= (on ENST00000506720 / NM_001322402.2; = p.V872= on NM_015236.6) | Silent (SNP) | VAF 145/243 reads (60%) | catalogued as COSV72231858; called by muse, mutect2, varscan2
- AHCTF1 | c.576T>A p.A192= (on ENST00000366508; = p.A166= on NM_015446.5) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV58254858; called by muse, mutect2, varscan2
- AKAP4 | c.549A>G p.K183= | Silent (SNP) | VAF 61/246 reads (25%) | catalogued as rs782354148, COSV62075414; called by muse, mutect2, varscan2
- ALOXE3 | c.390G>T p.L130= | Silent (SNP) | VAF 56/79 reads (71%) | catalogued as COSV59077845; called by muse, mutect2, varscan2
- AP2B1 | c.669G>A p.L223= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as COSV52003261; called by muse, mutect2, varscan2
- APC2 | c.6732C>T p.F2244= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV52021900; called by muse, mutect2, varscan2
- ARHGAP30 | c.2512C>A p.R838= | Silent (SNP) | VAF 107/224 reads (48%) | catalogued as COSV63519138; called by muse, mutect2, varscan2
- ARNT | c.936C>T p.I312= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV62232217; called by muse, mutect2, varscan2
- ARVCF | c.705C>G p.A235= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV54269905, COSV99599497; called by muse, mutect2, varscan2
- ASB16 | c.501C>A p.A167= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV53236385; called by muse, mutect2, varscan2
- ASTN2 | c.1944C>A p.S648= (on ENST00000313400 / NM_001365069.1; = p.S597= on NM_014010.5) | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV57815371; called by muse, mutect2, varscan2
- ATG2B | c.2679A>G p.L893= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV63425344; called by muse, mutect2
- ATG2B | c.2067G>T p.V689= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV63425353; called by muse, mutect2, varscan2
- ATXN2 | c.1770G>T p.S590= (on ENST00000550104; = p.S430= on NM_002973.4) | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV66482021, COSV66485891; called by muse, mutect2, varscan2
- ATXN3L | c.1014C>A p.V338= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as COSV66075246, COSV66076222; called by muse, mutect2, varscan2
- BNC1 | c.432G>A p.L144= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as rs535713259, COSV61759057; called by muse, mutect2, varscan2
- BORA | c.642T>A p.V214= (on ENST00000613797; = p.V139= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV64695843; called by muse, mutect2, varscan2
- BRD8 | c.2121G>A p.Q707= (on ENST00000254900 / NM_139199.2; = p.Q780= on NM_006696.4) | Silent (SNP) | VAF 46/75 reads (61%) | catalogued as COSV50167756; called by muse, mutect2, varscan2
- C1QL1 | c.396C>T p.F132= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV53648082; called by muse, mutect2, varscan2
- C1QTNF3 | c.411C>T p.F137= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV51469875; called by muse, mutect2, varscan2
- CASP1 | c.102G>A p.V34= | Silent (SNP) | VAF 104/203 reads (51%) | catalogued as COSV62057452; called by muse, mutect2, varscan2
- CCR7 | c.621G>A p.A207= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs759442446, COSV55850442; called by muse, mutect2, varscan2
- CDK8 | c.375G>T p.R125= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV67423016; called by muse, mutect2, varscan2
- CELSR1 | c.8811G>T p.P2937= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV53099169; called by muse, mutect2, varscan2
- CEP170B | c.2739G>A p.L913= (on ENST00000453495; = p.L842= on NM_015005.3) | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV69026431; called by muse, mutect2, varscan2
- CFAP65 | c.921T>C p.F307= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV55391840, COSV99838476; called by muse, mutect2, varscan2
- CLSTN2 | c.2019C>A p.A673= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV71724744, COSV71724995; called by muse, mutect2, varscan2
- CNMD | c.111G>A p.A37= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1408851901, COSV65034028; called by muse, mutect2, varscan2
- COL5A1 | c.1155C>T p.N385= | Silent (SNP) | VAF 54/78 reads (69%) | catalogued as COSV65674265; called by muse, mutect2, varscan2
- CPZ | c.672C>A p.V224= (on ENST00000360986 / NM_001014447.3; = p.V213= on NM_003652.3) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV59925913; called by muse, mutect2, varscan2
- CR1L | c.1095A>T p.P365= | Silent (SNP) | VAF 72/291 reads (25%) | catalogued as COSV54331247; called by muse, mutect2, varscan2
- CROCC | c.1542C>A p.A514= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV65014739; called by muse, mutect2, varscan2
- CRYBG1 | c.1410G>T p.P470= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV64814457; called by muse, mutect2, varscan2
- CTNNA2 | c.2307A>T p.S769= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV58178194; called by muse, mutect2, varscan2
- DCAF4L2 | c.645G>A p.T215= | Silent (SNP) | VAF 62/165 reads (38%) | catalogued as rs768466828, COSV60479814, COSV60480247, COSV60482124; called by muse, mutect2, varscan2
- DCLK3 | c.1566C>T p.P522= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs533228666, COSV101374117; called by muse, mutect2, varscan2
- DCLRE1B | c.666G>T p.V222= | Silent (SNP) | VAF 46/77 reads (60%) | catalogued as COSV65813604; called by muse, mutect2, varscan2
- DDX10 | c.96C>T p.N32= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as rs1172218095, COSV59439577; called by muse, mutect2, varscan2
- DDX42 | c.606C>T p.P202= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as COSV63791308; called by muse, mutect2, varscan2
- DHX37 | c.2487G>A p.L829= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV58139168; called by muse, mutect2, varscan2
- DPYSL3 | c.1081C>A p.R361= | Silent (SNP) | VAF 51/81 reads (63%) | catalogued as COSV58330790, COSV58330963; called by muse, mutect2, varscan2
- DTX1 | c.1059C>T p.A353= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV57498468, COSV57500819; called by muse, mutect2, varscan2
- E2F7 | c.2643A>G p.G881= | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as COSV59743331; called by muse, mutect2, varscan2
- EHBP1 | c.1254A>T p.T418= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as COSV50436633; called by muse, mutect2, varscan2
- ENTPD6 | c.234C>G p.A78= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV61752396; called by muse, mutect2, varscan2
- FAM8A1 | c.690G>T p.P230= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV52583180; called by muse, mutect2, varscan2
- FANCM | c.3528C>T p.F1176= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV57506184; called by muse, mutect2, varscan2
- FAT2 | c.510G>T p.V170= | Silent (SNP) | VAF 63/115 reads (55%) | catalogued as COSV55828792; called by muse, mutect2, varscan2
- FCER1A | c.765A>G p.K255= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs747269017, COSV63668359; called by muse, mutect2, varscan2
- FECH | c.276C>T p.L92= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV50492630; called by muse, mutect2, varscan2
- FMN2 | c.3585A>T p.I1195= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV60452008; called by muse, mutect2, varscan2
- FMNL2 | c.378G>A p.L126= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99980464; called by muse, mutect2
- GAB1 | c.2040G>A p.G680= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs763859429, COSV53760837; called by muse, mutect2, varscan2
- GALNT14 | c.1509C>G p.T503= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV61110738; called by muse, mutect2, varscan2
- GBA | c.90A>T p.L30= | Silent (SNP) | VAF 65/277 reads (23%) | catalogued as COSV59170963; called by muse, mutect2, varscan2
- GOLGA6A | c.624G>T p.R208= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as COSV51806967; called by muse, mutect2, varscan2
- GON4L | c.2055A>C p.P685= | Silent (SNP) | VAF 79/175 reads (45%) | catalogued as COSV55203350; called by muse, mutect2, varscan2
- GRIN3A | c.279G>T p.P93= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV62457905; called by muse, mutect2, varscan2
- GTF3C1 | c.558G>T p.R186= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV62244682; called by muse, mutect2, varscan2
- HCN1 | c.1599A>G p.T533= | Silent (SNP) | VAF 89/134 reads (66%) | catalogued as COSV57535553; called by muse, mutect2, varscan2
- HERC2 | c.2751A>T p.S917= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV55348676; called by muse, mutect2, varscan2
164 further variants in this file (0 protein-altering or splice-affecting, 143 silent, 21 other) are not listed here.
